Somatic mutation profile of tumor specimen 0E1KON from CCDI case PBCWNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1KON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d7574a-55a8-4cf6-ba3e-ffd617bc69f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KOB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de5729d8-eeaa-4dda-ac60-90b2a3e0e7f5

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANK1 | c.2698+1G>T p.X900_splice | Splice Site (SNP) | VAF 98/238 reads (41%) | catalogued as CS1513529; called by muse, mutect2, varscan2
- OR5T2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 177/728 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs770835107, COSV57589665, COSV57590384; called by muse, mutect2, varscan2
- ZPLD1 | c.182C>A p.S61* (on ENST00000466937 / NM_001329788.1; = p.S77* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 198/499 reads (40%) | catalogued as rs1260956101, COSV60355589; called by muse, mutect2, varscan2
- ADAM29 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.9373G>T p.V3125L | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HPS6 | c.626G>T p.W209L | Missense Mutation (SNP) | VAF 31/516 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- KIF21B | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 180/426 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTOG | c.3968T>C p.V1323A | Missense Mutation (SNP) | VAF 22/745 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.048); called by muse, mutect2
- PCDH7 | c.1113C>A p.H371Q | Missense Mutation (SNP) | VAF 177/460 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PTGER1 | c.97_111del p.G33_A37del | In Frame Del (DEL) | VAF 102/312 reads (33%) | called by mutect2, varscan2
- SH3TC2 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 28/498 reads (6%) | called by muse, mutect2
- TMEM132D | c.2813G>C p.C938S | Missense Mutation (SNP) | VAF 127/472 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCSK5 | c.1900+27G>C | Intron (SNP) | VAF 84/207 reads (41%) | called by muse, mutect2, varscan2
